Gene-level copy-number profile of specimen HCM-BROD-0485-C15-85M from HCMI case HCM-BROD-0485-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 46.5 years (16,967 days).
Specimen HCM-BROD-0485-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d93c11fa-0cd2-42c5-80ff-f31e886b582f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0485-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,760 have no estimate.
https://portal.gdc.cancer.gov/files/0c91a884-a2cb-44c8-81ae-7901182e37f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 13,796; copy number 2: 32,480; copy number 3: 10,766; copy number 4: 801; copy number 5: 272; copy number 6: 500; copy number 7: 130; copy number 8: 7; copy number 10: 49; copy number 14: 2; copy number 15: 1; copy number 17: 15; copy number 72: 3; copy number 101: 30.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,290,513–149,290,762, 1 gene (within-gene range 0–1): 7SK.
- chr6:161,347,417–163,315,492, 10 genes (within-gene range 0–2): PRKN, AL132982.1, AL138716.1, KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,009 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,706,901–24,112,135, 18 genes, copy number 5 (within-gene range 3–5): ELOA-AS1, ELOA, PITHD1, LYPLA2, GALE, HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1, AL591178.1, MYOM3, MYOM3-AS1.
- chr2:19,910,263–20,823,130, 27 genes, copy number 6–17: WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH.
- chr3:167,392,796–167,825,569, 7 genes, copy number 5: LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1.
- chr3:168,249,522–174,286,644, 95 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:174,057,641–179,789,401, 72 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr3:193,593,144–194,260,720, 17 genes, copy number 6: OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037.
- chr3:196,983,890–197,303,755, 6 genes, copy number 5–6: RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1.
- chr3:197,509,783–197,573,323, 1 gene, copy number 5: BDH1.
- chr3:197,737,179–198,123,232, 17 genes, copy number 5–7 (within-gene range 4–7): FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr8:23,135,588–23,190,675, 2 genes, copy number 5 (within-gene range 3–5): TNFRSF10D, TNFRSF10A-AS1.
- chr8:78,605,952–78,609,705, 1 gene, copy number 5: AC068700.1.
- chr8:118,189,455–145,066,685, 472 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:20,361,732–25,814,171, 82 genes, copy number 10–101 (broad region; genes not listed).
- chr14:18,333,726–18,343,144, 2 genes, copy number 5–6: CR383658.1, RNU6-458P.
- chr17:74,747,319–74,776,367, 4 genes, copy number 5 (within-gene range 4–5): AC016888.1, MIR3615, SLC9A3R1, NAT9.
- chr17:75,261,674–75,856,507, 32 genes, copy number 5 (within-gene range 4–5): MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2.
- chr18:57,352,557–58,986,480, 40 genes, copy number 5–15: ST8SIA3, AC090340.1, ONECUT2, FECH, AC100847.1, NARS1, AC027097.1, AC027097.2, ATP8B1, RNU6-742P, RSL24D1P11, LINC01897, HMGN1P30, NEDD4L, AC107896.1, AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P.
- chr19:14,840,466–16,690,023, 112 genes, copy number 7 (broad region; genes not listed).
- chr21:8,603,547–8,680,934, 2 genes, copy number 7: RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 10,960. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
